Gene-level copy-number profile of tumor specimen TCGA-P5-A72W-01A from TCGA case TCGA-P5-A72W, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Astrocytoma, anaplastic; Tissue or organ of origin: Cerebrum; Tumor grade: G3; Age at diagnosis: 35.2 years (12,848 days).
Specimen TCGA-P5-A72W-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LGG.21567208-49f9-42c7-a869-b52a8b0787c4.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-P5-A72W-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 804 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; AscatNGS; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/6b795810-a8aa-40d2-849b-22dc424ae429

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 741; copy number 2: 5,171; copy number 3: 4,806; copy number 4: 46,143; copy number 5: 2,478; copy number 6: 315; copy number 8: 5; copy number 10: 159; copy number 11: 1.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-P5-A72W-01A-11D-A32A-01): tumor purity 0.81, ploidy 3.84, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 160 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:111,621,458–113,616,958, 11 genes, copy number 10: H2AZP7, AC022360.1, RNU4-37P, CSMD3, AC024996.1, RPL30P16, MIR2053, AC107890.1, AC055788.2, AC055788.1, AC103993.1.
- chr8:122,414,332–130,443,674, 148 genes, copy number 10 (within-gene range 8–10) (broad region; genes not listed).
- chr8:131,129,761–131,144,948, 1 gene, copy number 11: AC087341.1.

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
